Somatic mutation profile of tumor specimen MP2PRT-PATARG-TMP1-A (aliquot MP2PRT-PATARG-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PATARG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,224 days).
Specimen MP2PRT-PATARG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9deb5a5-71ae-469d-872f-e8c07ba8e3cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATARG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATARG-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06526b35-98c4-468e-863e-c75106f00546

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, 3'Flank 1, Splice Site 1, Frame Shift Ins 1, Frame Shift Del 1, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 41/219 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 34/218 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CACNA1G | c.6395G>A p.R2132H | Missense Mutation (SNP) | VAF 33/302 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as rs867781260, COSV100661742; called by muse, mutect2, varscan2
- CDKN2A | c.157_158insGG p.M53Rfs*2 | Frame Shift Ins (INS) | VAF 163/360 reads (45%) | catalogued as COSV58689610; called by mutect2, pindel, varscan2
- HSD3B1 | c.1087C>T p.R363W | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs368595612; called by muse, mutect2, varscan2
- ISOC2 | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 161/344 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as rs769034749; called by muse, mutect2, varscan2
- LAMB4 | c.1360+1G>A p.X454_splice | Splice Site (SNP) | VAF 38/155 reads (25%) | catalogued as rs541782494, COSV52720395; called by muse, mutect2, varscan2
- TRPM7 | c.5379del p.F1793Lfs*6 | Frame Shift Del (DEL) | VAF 8/86 reads (9%) | catalogued as rs1166584314; called by mutect2, pindel
- ZNF274 | c.493C>T p.R165W (on ENST00000610905; = p.R60W on NM_016324.3) | Missense Mutation (SNP) | VAF 141/329 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs768753500; called by muse, mutect2, varscan2
- ADGRV1 | c.2738T>G p.V913G | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.893); called by muse, varscan2
- CRB1 | c.2638A>T p.N880Y | Missense Mutation (SNP) | VAF 100/218 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMEM132B | c.3067A>G p.R1023G | Missense Mutation (SNP) | VAF 85/216 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MXRA5 | c.3303T>C p.G1101= | Silent (SNP) | VAF 194/443 reads (44%) | called by muse, mutect2, varscan2
- FHOD3 | c.1197-4677G>A | Intron (SNP) | VAF 81/294 reads (28%) | catalogued as rs1014767571; called by muse, mutect2, varscan2
- IGKV1OR2-108 | chr2:113406872 ins CCC | 3'Flank (INS) | VAF 14/84 reads (17%) | called by pindel, varscan2
